Somatic mutation profile of tumor specimen TCGA-22-5478-01A (aliquot TCGA-22-5478-01A-01D-1632-08) from TCGA case TCGA-22-5478, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.3 years (28,978 days).
Specimen TCGA-22-5478-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3230123-79e3-4825-870e-46c3e1fa504f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5478-11A (Solid Tissue Normal), aliquot TCGA-22-5478-11A-11D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f12ed17b-75b3-4216-a0c6-98689febcbf6

The open-access MAF lists 197 somatic variants for this specimen: 147 protein-altering or splice-affecting, 44 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 44, Nonsense Mutation 7, Frame Shift Del 7, Intron 3, Frame Shift Ins 3, Splice Site 2, Splice Region 2, 5'Flank 2, Nonstop Mutation 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCB9 | c.1859A>G p.N620S (on ENST00000280560 / NM_019625.4; = p.N577S on NM_019624.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs765484313, COSV54893422; called by muse, mutect2, varscan2
- AFP | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.251); catalogued as COSV56926370; called by muse, mutect2, varscan2
- AGTR2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs782115628, COSV64156824; called by muse, mutect2, varscan2
- AHNAK | c.3505G>T p.V1169L | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV57223850; called by muse, mutect2, varscan2
- ALDH6A1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs779088875, COSV63246974; called by muse, mutect2, varscan2
- ANK1 | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV55888347; called by muse, mutect2, varscan2
- ANK2 | c.5064G>C p.Q1688H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV52172533; called by muse, mutect2, varscan2
- ANO6 | c.2657T>C p.M886T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1287814300, COSV57665167; called by muse, mutect2, varscan2
- BANK1 | c.2231A>G p.H744R | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59847156; called by muse, mutect2, varscan2
- BCAR1 | c.2284G>T p.V762L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV50793864; called by muse, mutect2, varscan2
- BLK | c.1181-1G>A p.X394_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as rs922956428, COSV52054576; called by muse, mutect2, varscan2
- CCDC14 | c.1316T>A p.I439K (on ENST00000488653; = p.I391K on NM_022757.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV59946690; called by muse, mutect2, varscan2
- CCR4 | c.48C>A p.Y16* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV58383230; called by muse, mutect2, varscan2
- CFAP54 | c.7364T>C p.M2455T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs1482796559, COSV61573919; called by muse, mutect2, varscan2
- CFAP61 | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640408; called by muse, mutect2, varscan2
- CFL1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV57381008; called by muse, mutect2, varscan2
- CLEC3A | c.263A>T p.Y88F (on ENST00000651443; = p.Y79F on NM_005752.6) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.779); catalogued as COSV55222820; called by muse, mutect2, varscan2
- CLHC1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 55/128 reads (43%) | catalogued as COSV68464657; called by muse, mutect2, varscan2
- DBI | c.218C>G p.A73G (on ENST00000355857 / NM_001079862.3; = p.A90G on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV61056575; called by muse, mutect2, varscan2
- DDX17 | c.2050C>G p.R684G | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.28); catalogued as COSV53246938; called by muse, mutect2, varscan2
- DICER1 | c.4548A>T p.K1516N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58625074; called by muse, mutect2, varscan2
- DNMT3B | c.2232G>T p.R744S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV52421426; called by muse, mutect2, varscan2
- DPPA4 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as COSV59511908; called by muse, mutect2, varscan2
- DYSF | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV50509112; called by muse, mutect2, varscan2
- EIF4B | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV50405764; called by muse, mutect2, varscan2
- ELOA2 | c.1298T>A p.V433D | Missense Mutation (SNP) | VAF 189/280 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55304483; called by muse, mutect2, varscan2
- F11 | c.881C>A p.S294* | Nonsense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV53008558; called by muse, mutect2, varscan2
- F13B | c.1518C>A p.N506K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV66374457, COSV66375026; called by muse, mutect2, varscan2
- FAM135B | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52742726; called by muse, mutect2, varscan2
- FAM228A | c.620G>T p.*207Lext*42 | Nonstop Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV54596047; called by muse, mutect2
- FCN1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779669688, COSV65662480; called by muse, mutect2, varscan2
- FMN2 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753648480, COSV60443994; called by muse, mutect2, varscan2
- FOLH1 | c.1871C>A p.T624K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759009835, COSV57053639; called by muse, mutect2, varscan2
- FTHL17 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV63267552; called by muse, mutect2, varscan2
- FUT9 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56152591; called by muse, mutect2, varscan2
- GALNT14 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV61104719; called by muse, mutect2, varscan2
- GAREM1 | c.2455T>G p.S819A (on ENST00000269209 / NM_001242409.2; = p.S818A on NM_022751.3) | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.294); catalogued as COSV52507745; called by muse, mutect2, varscan2
- GDF3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV61713300; called by muse, mutect2
- GSTM5 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV56656406; called by muse, mutect2, varscan2
- GZF1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV57637332; called by muse, mutect2
- HCK | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs149121640; called by muse, mutect2, varscan2
- HDAC9 | c.1954A>T p.T652S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67780953; called by muse, mutect2, varscan2
- HEG1 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1013646848, COSV60764214; called by muse, mutect2, varscan2
- HK2 | c.2087T>A p.V696E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51876046; called by muse, mutect2, varscan2
- HORMAD1 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59272519; called by muse, mutect2, varscan2
- ITGB1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1188493444, COSV56480560; called by muse, mutect2, varscan2
- KALRN | c.8861G>A p.R2954H (on ENST00000360013 / NM_001024660.4; = p.R1257H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1559891981, COSV52249201; called by muse, mutect2, varscan2
- KCND2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV100476008, COSV58579504, COSV58596539; called by muse, mutect2, varscan2
- KDM5B | c.1529A>G p.Y510C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764704460, COSV52510834; called by muse, mutect2, varscan2
- KMT2B | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55866065; called by muse, mutect2
- KMT2E | c.186G>T p.A62= | Splice Region (SNP) | VAF 32/218 reads (15%) | catalogued as COSV57571709, COSV57577402; called by muse, mutect2
- KRTAP12-2 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs200766354; called by muse, mutect2, varscan2
- LACTB2 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV52568942; called by muse, mutect2, varscan2
- LIMD2 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51992327; called by muse, mutect2, varscan2
- LLGL2 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs139000321; called by muse, mutect2, varscan2
- LRFN5 | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53268790; called by muse, mutect2, varscan2
- LRRC37A3 | c.3854C>T p.A1285V | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58536188; called by muse, mutect2
- LRRIQ4 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61619859; called by muse, mutect2, varscan2
- LZTFL1 | c.44T>A p.I15N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV56112053; called by muse, mutect2, varscan2
- LZTS2 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV64652402; called by muse, mutect2
- MAP1S | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60723733; called by muse, mutect2, varscan2
- MAP3K15 | c.3473G>A p.G1158D | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58835157; called by muse, mutect2, varscan2
- MARCHF6 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as COSV56884668; called by muse, mutect2, varscan2
- MBD1 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs115426299, COSV54004920; called by muse, mutect2, varscan2
- MEMO1 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs756828361, COSV54455165; called by muse, mutect2, varscan2
- MFSD8 | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV56552244; called by muse, mutect2, varscan2
- MOGAT3 | c.486G>C p.M162I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV56176013, COSV99777288; called by muse, mutect2
- MPHOSPH10 | c.1831A>T p.S611C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54915956; called by muse, mutect2, varscan2
- MTMR6 | c.255A>T p.E85D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV67809200; called by muse, mutect2, varscan2
- MUC16 | c.13715C>A p.S4572Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV67481452; called by muse, mutect2, varscan2
- MUC16 | c.7990T>G p.S2664A | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV67481457; called by muse, mutect2, varscan2
- NCKAP5 | c.5089G>T p.D1697Y | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58463441; called by muse, mutect2, varscan2
- NOP53 | c.629A>C p.D210A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55882666; called by muse, mutect2, varscan2
- OR10J3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs369650761; called by muse, mutect2, varscan2
- OR2F1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV67331784; called by muse, mutect2, varscan2
- OR2W3 | c.654C>G p.Y218* | Nonsense Mutation (SNP) | VAF 43/183 reads (23%) | catalogued as COSV64457632, COSV64458404; called by muse, mutect2, varscan2
- OR4S2 | c.914T>A p.F305Y | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV104395523, COSV56747786; called by muse, mutect2, varscan2
- OR52B6 | c.451T>A p.Y151N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61448132; called by muse, mutect2, varscan2
- OR52J3 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66746761; called by muse, mutect2, varscan2
- OR5W2 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV60617601; called by muse, mutect2, varscan2
- OR6Y1 | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56930654, COSV56931359; called by muse, mutect2, varscan2
- OR6Y1 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56930675; called by muse, mutect2
- OR8A1 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV52508048, COSV52509473; called by muse, mutect2, varscan2
- OR8K3 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57131306, COSV57132387; called by muse, mutect2, varscan2
- PCDHB6 | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782712059, COSV50692825, COSV50693880; called by muse, mutect2, varscan2
- PCLO | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs760296228, COSV61654164; called by muse, mutect2, varscan2
- PLA2G2F | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445632091, COSV64280213; called by muse, mutect2, varscan2
- PLA2G4A | c.1580-1G>T p.X527_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV66553032, COSV66554631; called by muse, mutect2, varscan2
- PLAC8 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61048048; called by muse, mutect2, varscan2
- POLN | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs756800435, COSV67026723; called by muse, mutect2, varscan2
- POLR2B | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs373213737; called by muse, mutect2, varscan2
- PPP1R13L | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1318970413, COSV62909227; called by muse, mutect2, varscan2
- PPP1R3A | c.1316A>G p.D439G | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1214384132, COSV52889123; called by muse, mutect2, varscan2
- RASGRF1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV69181685; called by muse, mutect2, varscan2
- REG1A | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52070811; called by muse, mutect2, varscan2
- RIMBP2 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55479851; called by muse, mutect2, varscan2
- RYR1 | c.14092G>T p.V4698L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV62097003, COSV62105036; called by muse, mutect2
- SCN10A | c.1856C>A p.S619Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101479307, COSV71862334; called by muse, mutect2, varscan2
- SEPSECS | c.845T>A p.L282* | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | catalogued as COSV57206830; called by muse, mutect2, varscan2
- SERPINA3 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs754963974, COSV67586793; called by muse, mutect2, varscan2
- SFMBT2 | c.2633G>C p.C878S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62814040; called by mutect2, varscan2
- SHROOM3 | c.2664C>G p.S888R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56036075; called by muse, mutect2, varscan2
- SLC16A6 | c.1207C>A p.H403N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59178589; called by muse, mutect2, varscan2
- SLC38A11 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58055297; called by muse, mutect2, varscan2
- SLCO4A1 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53890206; called by muse, mutect2, varscan2
- SLITRK1 | c.1941G>T p.K647N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65676907; called by muse, mutect2, varscan2
- SNRPD2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV50003810; called by muse, mutect2
- SRRM1 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV60479427; called by muse, mutect2, varscan2
- TAS1R3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.372); catalogued as COSV59564735; called by muse, mutect2
- TBC1D1 | c.1629A>G p.K543= | Splice Region (SNP) | VAF 8/99 reads (8%) | catalogued as COSV54724176; called by muse, mutect2
- TCF25 | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54531277; called by muse, mutect2
- TCTEX1D1 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 46/143 reads (32%) | catalogued as COSV51075242, COSV51076418; called by muse, mutect2, varscan2
- TDRD5 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs145054790, COSV54242045, COSV99677172; called by muse, mutect2, varscan2
- TFPI2 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55991489; called by muse, mutect2, varscan2
- TGS1 | c.1070G>T p.C357F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV52702126; called by muse, mutect2, varscan2
- TNRC6A | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.261); catalogued as COSV59368159; called by muse, mutect2
- TRIM22 | c.559T>A p.F187I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66091401; called by muse, mutect2, varscan2
- TRMT9B | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV71600559; called by muse, mutect2, varscan2
- TRPM1 | c.2390C>A p.A797D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV56639127; called by muse, mutect2, varscan2
- TTC14 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56013390; called by muse, mutect2, varscan2
- VDR | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57469533; called by muse, mutect2, varscan2
- WDR35 | c.3314A>G p.Y1105C (on ENST00000345530 / NM_001006657.2; = p.Y1094C on NM_020779.4) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1307362688, COSV55605299; called by muse, mutect2, varscan2
- WNK1 | c.3193G>A p.A1065T (on ENST00000315939 / NM_018979.4; = p.A818T on NM_014823.3) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV60041169; called by muse, mutect2, varscan2
- ZFHX4 | c.7571T>G p.L2524R | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51480974; called by muse, mutect2
- ZNF202 | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV60247966; called by muse, mutect2, varscan2
- ZNF208 | c.2369C>A p.A790E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV68110442; called by muse, mutect2, varscan2
- ZNF235 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52157731; called by muse, mutect2, varscan2
- ZNF254 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61644001; called by muse, mutect2, varscan2
- ZNF292 | c.6227A>T p.Q2076L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV60543994; called by muse, mutect2, varscan2
- ZNF516 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101487194; called by mutect2, varscan2
- ZNF568 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV61741022, COSV61742443; called by muse, mutect2
- ZNF594 | c.1467G>T p.Q489H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV68385887; called by muse, mutect2, varscan2
- ZXDC | c.1565C>G p.A522G | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60447934; called by muse, mutect2, varscan2
- ADH1B | c.680dup p.D228Gfs*13 | Frame Shift Ins (INS) | VAF 105/510 reads (21%) | called by mutect2, pindel, varscan2
- FAM47A | c.1617_1655del p.R544_L556del | In Frame Del (DEL) | VAF 9/36 reads (25%) | called by muse*, pindel
- HYAL4 | c.516del p.D173Ifs*14 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- MRC1 | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- MRC1 | c.3185A>G p.E1062G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- NTNG2 | c.607del p.A203Qfs*166 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- P4HA3 | c.920_923del p.T307Rfs*88 | Frame Shift Del (DEL) | VAF 28/161 reads (17%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.816del p.V273Sfs*39 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- RYR2 | c.7577del p.P2526Hfs*3 | Frame Shift Del (DEL) | VAF 27/132 reads (20%) | called by mutect2, pindel, varscan2
- SLC27A2 | c.369dup p.L124Afs*50 | Frame Shift Ins (INS) | VAF 19/132 reads (14%) | called by mutect2, pindel, varscan2
- STARD4 | c.422del p.K141Rfs*29 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- UMOD | c.1720dup p.M574Nfs*3 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- ACAP1 | c.1908G>C p.A636= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV50138909; called by muse, mutect2
- ATG9A | c.682C>T p.L228= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV63446260; called by muse, mutect2, varscan2
- CACNG8 | c.762G>T p.G254= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV54416089; called by muse, mutect2, varscan2
- CAPN6 | c.1320C>T p.Y440= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV60696320; called by muse, mutect2, varscan2
- CBX4 | c.1374G>C p.P458= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV53966982; called by muse, mutect2, varscan2
- CRTC1 | c.981C>G p.P327= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as COSV58721632; called by muse, mutect2
- CSTF2 | c.258A>T p.A86= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV63376365, COSV63376436; called by muse, mutect2, varscan2
- CYP2C18 | c.1281T>A p.P427= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV53674039; called by muse, mutect2, varscan2
- DCAF1 | c.789A>G p.G263= | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as COSV60045375; called by muse, mutect2, varscan2
- DMBT1 | c.304C>T p.L102= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV57553389; called by muse, mutect2, varscan2
- DNAH3 | c.3162T>C p.C1054= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV54539202; called by muse, mutect2, varscan2
- DOCK2 | c.4308C>A p.S1436= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV56976686; called by muse, mutect2, varscan2
- ECE2 | c.66T>A p.L22= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs764776942, COSV100668361; called by muse, varscan2
- FAM47B | c.436C>T p.L146= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV61454146, COSV61455865; called by muse, mutect2
- IFIT1 | c.87C>T p.D29= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs779730712, COSV65661386; called by muse, mutect2, varscan2
- LRRTM1 | c.174C>G p.T58= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV54444764, COSV99701781; called by muse, mutect2, varscan2
- MDN1 | c.16575T>C p.F5525= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV65526875; called by muse, mutect2, varscan2
- MEIS3 | c.714C>T p.D238= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs571859937, COSV58983336; called by muse, mutect2, varscan2
- MYO16 | c.3039A>G p.P1013= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs143387670, COSV62757490; called by muse, mutect2, varscan2
- MYO7B | c.6201G>A p.A2067= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs376669134; called by muse, mutect2, varscan2
- NXPE4 | c.1557A>G p.A519= (on ENST00000375478 / NM_001077639.2; = p.A235= on NM_017678.3) | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV64944164; called by muse, mutect2, varscan2
- OR10C1 | c.198C>A p.T66= (on ENST00000622521; = p.T64= on NM_013941.3) | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV65823649; called by muse, mutect2, varscan2
- OR52J3 | c.762C>A p.I254= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as COSV66746680, COSV66747476; called by muse, mutect2, varscan2
- OR56A3 | c.135C>G p.A45= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV61569741; called by muse, mutect2, varscan2
- OR6Y1 | c.735C>A p.T245= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV56930662; called by muse, mutect2
- PADI4 | c.1095C>A p.P365= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64924619; called by muse, mutect2, varscan2
- PCDH15 | c.4842C>A p.T1614= (on ENST00000644397 / NM_001354429.2; = p.T1556= on NM_001142771.2) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV64718229; called by muse, mutect2
- PCNX4 | c.1293A>G p.V431= (on ENST00000406854 / NM_001330177.2; = p.V197= on NM_022495.5) | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV58306416; called by muse, mutect2, varscan2
- PDHA2 | c.552C>T p.N184= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1448922583, COSV54779922; called by muse, mutect2, varscan2
- PRC1 | c.1548T>A p.S516= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV62696219; called by muse, mutect2, varscan2
- RABGAP1L | c.9C>T p.V3= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52314094; called by muse, mutect2, varscan2
- RSF1 | c.1821A>G p.P607= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as COSV57843603; called by muse, mutect2, varscan2
- SCAF11 | c.2934A>G p.P978= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as COSV65478174; called by muse, mutect2, varscan2
- SCN4A | c.5367G>T p.S1789= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV71125790, COSV71128063; called by muse, mutect2, varscan2
- SPTA1 | c.4123C>T p.L1375= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV63752687; called by muse, mutect2, varscan2
- ST8SIA3 | c.975A>G p.G325= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV60654846; called by muse, mutect2
- TFCP2 | c.465G>T p.P155= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs746185739, COSV56934820, COSV56934881; called by muse, mutect2
- TMEM132A | c.756G>T p.L252= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV50014792; called by muse, mutect2, varscan2
- TTN | c.82353T>C p.N27451= (on ENST00000591111; = p.N20027= on NM_003319.4) | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs1198077200, COSV60230957; called by muse, mutect2, varscan2
- TTN | c.55551T>A p.G18517= (on ENST00000591111; = p.G11093= on NM_003319.4) | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as COSV60231004; called by muse, mutect2
- UACA | c.2766C>T p.Y922= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs778595564, COSV59858188; called by muse, mutect2, varscan2
- VCAN | c.9624G>A p.L3208= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV54112433; called by muse, mutect2, varscan2
- ZAN | c.7689G>T p.T2563= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV61812815; called by muse, mutect2, varscan2
- ZNF257 | c.1197C>T p.A399= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV71310577; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826143 G>C | 5'Flank (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- CR2 | c.1979-213T>C | Intron (SNP) | VAF 45/122 reads (37%) | catalogued as COSV100889522; called by muse, mutect2, varscan2
- IL36B | c.261+889T>C | Intron (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99382451; called by muse, mutect2
- RNU6-104P | chr8:43301983 A>G | 5'Flank (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- SNORD116-25 | n.77_78del | RNA (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.10361-4518G>T | Intron (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100617453, COSV60231036; called by muse, mutect2, varscan2
